Somatic mutation profile of cancer-model specimen HCM-CSHL-0806-C54-85A (3D Organoid, passage 11; aliquot HCM-CSHL-0806-C54-85A-01D-A881-36), derived from the primary tumor of HCMI case HCM-CSHL-0806-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1.
Specimen HCM-CSHL-0806-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c5c06cc-03a8-4730-b90c-54b358ca9508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0806-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0806-C54-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a150018f-de40-4cdb-81e2-3716098318b2

The open-access MAF lists 637 somatic variants for this specimen: 476 protein-altering or splice-affecting, 139 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 375, Silent 139, Frame Shift Del 46, Nonsense Mutation 23, Frame Shift Ins 18, Intron 9, Splice Region 8, 3'UTR 5, 5'UTR 3, In Frame Ins 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 227/470 reads (48%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OPA1 | c.868C>T p.R290* (on ENST00000361510 / NM_130837.3; = p.R235* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 78/207 reads (38%) | catalogued as rs761743852, CM136994; ClinVar: pathogenic; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 156/328 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 94/260 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 216/217 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A3GALT2 | c.599T>G p.V200G | Missense Mutation (SNP) | VAF 28/825 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1432414969; called by muse, mutect2
- AADACL4 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 255/498 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs200338663; called by muse, mutect2, varscan2
- ABCC12 | c.4049C>T p.A1350V | Missense Mutation (SNP) | VAF 181/372 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs767290200; called by muse, varscan2
- ABCF3 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 99/224 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs756591208; called by muse, mutect2, varscan2
- ADAM15 | c.1505del p.P502Lfs*5 | Frame Shift Del (DEL) | VAF 266/680 reads (39%) | catalogued as rs1338607572; called by mutect2, pindel, varscan2
- AKAP6 | c.31del p.L11* | Frame Shift Del (DEL) | VAF 110/250 reads (44%) | catalogued as rs771895850; called by mutect2, varscan2
- ALOX12 | c.898dup p.L300Pfs*70 | Frame Shift Ins (INS) | VAF 49/464 reads (11%) | catalogued as rs1364468834; called by mutect2, pindel, varscan2
- AMOTL2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 44/745 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1475311303, COSV51438344; called by muse, mutect2
- ANK1 | c.1753G>A p.V585I | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs745525088, COSV55879510; called by muse, mutect2, varscan2
- ANKS4B | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 217/460 reads (47%) | catalogued as rs763113188; called by muse, mutect2, varscan2
- ANO3 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 147/297 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs748171802, COSV56787167; called by muse, mutect2, varscan2
- AP1B1 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 242/520 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376948907; called by muse, varscan2
- APEH | c.1531del p.H511Ifs*24 | Frame Shift Del (DEL) | VAF 176/430 reads (41%) | catalogued as COSV56535366; called by mutect2, pindel, varscan2
- ASGR1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 204/456 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1340268632, COSV52648428; called by muse, mutect2, varscan2
- ATM | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 113/237 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as rs200601781, COSV99592134; ClinVar: not provided / likely benign / uncertain significance; called by muse, mutect2, varscan2
- BAIAP3 | c.2873dup p.H959Pfs*66 | Frame Shift Ins (INS) | VAF 143/388 reads (37%) | catalogued as rs1313326417; called by mutect2, pindel, varscan2
- BBS9 | c.808dup p.C270Lfs*3 | Frame Shift Ins (INS) | VAF 182/415 reads (44%) | catalogued as rs1288376188; called by mutect2, varscan2
- BCL11B | c.1168C>T p.R390W (on ENST00000357195 / NM_001282237.2; = p.R319W on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/857 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61736114; called by muse, mutect2
- BHMT | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 38/598 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs748007994; called by muse, mutect2
- BICDL2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1035153431; called by muse, mutect2
- BUD23 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 134/263 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782264637; called by muse, mutect2, varscan2
- C1QTNF12 | c.853del p.A285Pfs*38 | Frame Shift Del (DEL) | VAF 277/727 reads (38%) | catalogued as rs764140303; called by mutect2, pindel, varscan2
- C20orf144 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 355/720 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs1404195579; called by muse, mutect2, varscan2
- C5 | c.628del p.S210Qfs*41 | Frame Shift Del (DEL) | VAF 170/439 reads (39%) | catalogued as COSV56326725; called by mutect2, pindel, varscan2
- C5orf38 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 401/873 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.268); catalogued as rs1231627026; called by muse, mutect2, varscan2
- C9orf131 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 43/584 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs111590922; called by muse, mutect2
- CACNA1B | c.4123G>A p.V1375M | Missense Mutation (SNP) | VAF 32/437 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs777421980, COSV53152730; called by muse, mutect2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 135/321 reads (42%) | catalogued as rs368765497; called by mutect2, pindel, varscan2
- CCDC168 | c.17512C>T p.R5838* | Nonsense Mutation (SNP) | VAF 36/602 reads (6%) | catalogued as rs371478604; called by muse, mutect2
- CCDC181 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 128/255 reads (50%) | catalogued as rs1375457947, COSV63156352; called by muse, mutect2, varscan2
- CCDC82 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 192/416 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs146108139; called by muse, mutect2, varscan2
- CCDC87 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 259/565 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374929199; called by muse, mutect2, varscan2
- CDH4 | c.1781del p.P594Rfs*35 | Frame Shift Del (DEL) | VAF 172/438 reads (39%) | catalogued as rs1367432489; called by mutect2, pindel, varscan2
- CELSR3 | c.3695G>A p.R1232Q | Missense Mutation (SNP) | VAF 219/489 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs758323399, COSV99373351; called by muse, varscan2
- CENPQ | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 101/232 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367615344, COSV59920891; called by muse, mutect2, varscan2
- CIT | c.5825C>T p.A1942V | Missense Mutation (SNP) | VAF 277/528 reads (52%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1156247906; called by muse, mutect2, varscan2
- CNGA4 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 254/572 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV66006361; called by muse, mutect2, varscan2
- CYB5A | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 183/407 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770734233, COSV55021610; called by muse, mutect2, varscan2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 102/232 reads (44%) | catalogued as rs762918884; called by mutect2, varscan2
- DCAF1 | c.2809dup p.Q937Pfs*20 | Frame Shift Ins (INS) | VAF 206/412 reads (50%) | catalogued as rs782606429; called by mutect2, varscan2
- DCAF17 | c.198A>G p.I66M | Missense Mutation (SNP) | VAF 25/388 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs775568340; called by muse, mutect2
- DDB1 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57102760; called by muse, mutect2
- DENND4C | c.3583G>A p.V1195I (on ENST00000434457 / NM_001330640.2; = p.V1146I on NM_017925.7) | Missense Mutation (SNP) | VAF 114/222 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs776596059, COSV100727537; called by muse, varscan2
- DHX30 | c.1756C>T p.R586W (on ENST00000445061 / NM_138615.3; = p.R547W on NM_014966.3) | Missense Mutation (SNP) | VAF 60/680 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs1309241437; called by muse, mutect2
- DHX38 | c.3556C>T p.R1186W | Missense Mutation (SNP) | VAF 172/391 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1021379081; called by muse, varscan2
- DKK4 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 18/632 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55183549; called by muse, mutect2
- DLGAP4 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 280/607 reads (46%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs202018894; called by muse, mutect2, varscan2
- DMGDH | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 222/417 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs765873369, COSV99669041; called by muse, mutect2, varscan2
- DMRTA2 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 124/632 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs780474137; called by muse, mutect2, varscan2
- DNAH11 | c.5507G>A p.R1836Q | Missense Mutation (SNP) | VAF 221/457 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs754715648, COSV100179089, COSV60945076; called by muse, mutect2, varscan2
- DOCK3 | c.3331C>T p.R1111W | Missense Mutation (SNP) | VAF 63/683 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774398189, COSV56509467; called by muse, mutect2
- DRC3 | c.612G>T p.K204N | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV58266959; called by muse, mutect2, varscan2
- EEF2K | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 223/496 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1427315364, COSV53786902; called by muse, mutect2, varscan2
- EPHA3 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 156/348 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146728702; called by muse, mutect2, varscan2
- ESS2 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 368/708 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs756678975; called by muse, varscan2
- ETF1 | c.1296dup p.D433* | Frame Shift Ins (INS) | VAF 164/410 reads (40%) | catalogued as rs34007600; called by mutect2, pindel, varscan2
- EXOC3 | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 40/658 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV59269171; called by muse, mutect2
- FAM236C | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 166/328 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1274426882; called by muse, mutect2, varscan2
- FAM90A1 | c.1121A>G p.Q374R | Missense Mutation (SNP) | VAF 249/804 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771576074; called by muse, mutect2, varscan2
- FAT3 | c.6922C>A p.Q2308K | Missense Mutation (SNP) | VAF 168/386 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV53107155; called by muse, mutect2, varscan2
- FBLN7 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 339/734 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs199980872; called by muse, mutect2, varscan2
- FGFRL1 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 358/738 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461069330, COSV99294580; called by muse, varscan2
- FIGNL2 | c.1093del p.E365Rfs*14 | Frame Shift Del (DEL) | VAF 346/858 reads (40%) | catalogued as rs1361047104; called by mutect2, pindel, varscan2
- FMNL3 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 151/351 reads (43%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.661); catalogued as rs1444059344, COSV53301283; called by muse, mutect2, varscan2
- FOXD4L1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 136/1022 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs768136068; called by muse, mutect2
- FRAS1 | c.3500G>A p.R1167H | Missense Mutation (SNP) | VAF 36/483 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376836345; called by muse, mutect2
- GAK | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 180/411 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as rs148765045; called by muse, mutect2, varscan2
- GGTLC1 | c.279del p.S94Hfs*58 | Frame Shift Del (DEL) | VAF 121/354 reads (34%) | catalogued as rs753146433; called by mutect2, pindel, varscan2
- GOLGA6A | c.1593G>A p.T531= | Splice Region (SNP) | VAF 84/862 reads (10%) | catalogued as rs758565193; called by muse, mutect2
- GOLGA6B | c.1593G>A p.T531= | Splice Region (SNP) | VAF 77/303 reads (25%) | catalogued as rs770908530; called by muse, mutect2, varscan2
- GOLGA6L2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.553); catalogued as rs566940056, COSV61475075; called by muse, varscan2
- GPR108 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 170/358 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as rs1030041616; called by muse, mutect2, varscan2
- GRM2 | c.1901T>C p.L634S | Missense Mutation (SNP) | VAF 246/522 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1294240913; called by muse, mutect2, varscan2
- GRTP1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 328/725 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as rs373647513; called by muse, mutect2, varscan2
- GSE1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 372/734 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV53674512; called by muse, varscan2
- GYG2 | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 23/773 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1439322735; called by muse, mutect2
- H2AJ | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 52/644 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1280757345; called by muse, mutect2
- HDAC2 | c.1172A>G p.H391R | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs1261159949; called by muse, mutect2
- HECW1 | c.4339C>T p.R1447W | Missense Mutation (SNP) | VAF 281/635 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765023043, COSV101223445, COSV101223887; called by muse, varscan2
- HELZ2 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 334/643 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs771605417, COSV64409045; called by muse, varscan2
- HSDL1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 197/452 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs146729333; called by muse, mutect2, varscan2
- HUWE1 | c.12020G>A p.R4007H | Missense Mutation (SNP) | VAF 228/450 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1556914313; called by muse, varscan2
- IFNG | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 168/353 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755519988, COSV57491375; called by muse, mutect2, varscan2
- IL10RA | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 237/535 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372372851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INF2 | c.3368C>T p.A1123V | Missense Mutation (SNP) | VAF 58/750 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1401317670; called by muse, mutect2
- INPP4A | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 165/374 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs764715229, COSV50864819; called by muse, mutect2, varscan2
- INPPL1 | c.3127_3129del p.E1043del | In Frame Del (DEL) | VAF 87/588 reads (15%) | catalogued as rs770954047; called by pindel, varscan2
- JKAMP | c.460G>A p.V154I (on ENST00000554271 / NM_001284201.1; = p.V140I on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755619284; called by muse, varscan2
- KAT2A | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 171/335 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1347629766, COSV52424926; called by muse, mutect2, varscan2
- KBTBD7 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV65266552; called by muse, varscan2
- KCNB2 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 18/717 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV73049570; called by muse, mutect2
- KCNG2 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 39/1074 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.46); catalogued as rs1308039557; called by muse, mutect2
- KCNS1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 23/942 reads (2%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1327655002, COSV60260042; called by muse, mutect2
- KCNV1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 143/338 reads (42%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as rs756504582, COSV52084851; called by muse, varscan2
- KDM4D | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 222/486 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs374912184; called by muse, varscan2
- KIF26A | c.3805del p.R1269Gfs*7 | Frame Shift Del (DEL) | VAF 326/796 reads (41%) | catalogued as rs1458694083, COSV59464465; called by mutect2, pindel, varscan2
- KIF27 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 144/425 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs550945409, COSV52829531; called by muse, mutect2, varscan2
- KIF7 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 339/628 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs143915145, CM1511082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL21 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 258/498 reads (52%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.989); catalogued as rs369981047; called by muse, mutect2, varscan2
- KLHL40 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 192/383 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as rs771229933; called by muse, mutect2, varscan2
- KRT1 | c.347del p.G116Vfs*61 | Frame Shift Del (DEL) | VAF 290/738 reads (39%) | catalogued as rs781403016; called by mutect2, pindel, varscan2
- LAMA5 | c.8003G>A p.R2668Q | Missense Mutation (SNP) | VAF 281/596 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs967471014, COSV53361912; called by muse, mutect2, varscan2
- LOXHD1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as rs779377762; ClinVar: uncertain significance; called by muse, varscan2
- LRATD2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1328564963; called by muse, mutect2
- LRIT2 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 196/436 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100928315; called by muse, mutect2, varscan2
- LRP2 | c.10234G>A p.A3412T | Missense Mutation (SNP) | VAF 48/449 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147922851; ClinVar: uncertain significance; called by mutect2, varscan2
- MACF1 | c.21008G>A p.R7003Q (on ENST00000372915; = p.R5048Q on NM_012090.5) | Missense Mutation (SNP) | VAF 119/326 reads (37%) | catalogued as rs570585623, COSV57127627; called by muse, mutect2, varscan2
- MADD | c.3107G>A p.S1036N | Missense Mutation (SNP) | VAF 150/366 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1260299500; called by muse, varscan2
- MAPRE3 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 197/434 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1175991309; called by muse, mutect2, varscan2
- MAT1A | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs377184051, COSV64745164; called by muse, mutect2
- MROH7 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 46/548 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs766757461, COSV59869041; called by muse, mutect2
- MTHFR | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 191/397 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs777918196, COSV64877411; called by muse, mutect2, varscan2
- MUC5B | c.7241G>A p.C2414Y | Missense Mutation (SNP) | VAF 18/747 reads (2%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1338503810; called by muse, mutect2
- MYH11 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 210/386 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401359617, COSV55554511; called by muse, varscan2
- MYPOP | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 161/363 reads (44%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1345284604; called by muse, mutect2, varscan2
- MYRIP | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 313/632 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1010215407, COSV100219424; called by muse, mutect2, varscan2
- NAPRT | c.567C>T p.G189= | Splice Region (SNP) | VAF 252/497 reads (51%) | catalogued as rs1179007077; called by muse, mutect2, varscan2
- NCBP2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 180/408 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1433793609, COSV58318059; called by muse, mutect2, varscan2
- NCL | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 64/816 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs745393684; called by muse, mutect2
- NEK7 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 160/346 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs754797321; called by muse, mutect2, varscan2
- NEURL4 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 269/641 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs573288123, COSV59759170; called by muse, mutect2, varscan2
- NHSL1 | c.3079G>A p.A1027T | Missense Mutation (SNP) | VAF 23/669 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.898); catalogued as rs894256248, COSV58675415; called by muse, mutect2
- NPBWR1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 24/912 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.061); catalogued as COSV58695417; called by muse, mutect2
- NSMAF | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 216/461 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs779054438; called by muse, mutect2, varscan2
- OCSTAMP | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 20/692 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs956842427, COSV54097005; called by muse, mutect2
- OR10AC1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 287/591 reads (49%) | SIFT tolerated, low confidence (0.11); catalogued as rs1258162499; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 230/474 reads (49%) | catalogued as rs755413956; called by mutect2, varscan2
- OR56B1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 141/280 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV57723320; called by muse, mutect2, varscan2
- ORAI2 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 142/316 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs375636106; called by muse, varscan2
- ORC1 | c.2030G>A p.C677Y | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV65365081; called by muse, varscan2
- OSMR | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 27/548 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1450788526, COSV57086203; called by muse, mutect2
- PCDHGA1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 227/481 reads (47%) | catalogued as rs781690081, COSV65295069; called by muse, mutect2, varscan2
- PCDHGC3 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 259/538 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52768976; called by muse, mutect2, varscan2
- PCMTD1 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as rs879113184; called by muse, mutect2, varscan2
- PDZD3 | c.1682C>T p.A561V (on ENST00000531114; = p.A481V on NM_024791.4) | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs866192091; called by muse, mutect2, varscan2
- PDZD7 | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 284/578 reads (49%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.911); catalogued as rs1303874165; called by muse, mutect2, varscan2
- PGBD4 | c.1753del p.Y585Ifs*20 | Frame Shift Del (DEL) | VAF 131/387 reads (34%) | catalogued as COSV56626432; called by mutect2, pindel, varscan2
- PKHD1L1 | c.6851G>T p.R2284L | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101005302, COSV65747020; called by muse, varscan2
- PLXNB2 | c.5201C>T p.S1734F | Missense Mutation (SNP) | VAF 204/393 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63782393; called by muse, mutect2, varscan2
- PNPLA2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 363/694 reads (52%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs905195009; called by muse, varscan2
- PPP1R10 | c.2808del p.L939Cfs*109 | Frame Shift Del (DEL) | VAF 183/508 reads (36%) | catalogued as COSV64738548; called by mutect2, pindel, varscan2
- PPP1R3F | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 308/658 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.06); catalogued as rs1557121325, COSV99278999; called by muse, mutect2, varscan2
- PSMB6 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 42/541 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs768105769; called by muse, mutect2
- PTPRJ | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 249/533 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs374139660; called by muse, mutect2
- PTPRN | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 41/692 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs577458764; called by muse, mutect2
- PXDN | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 290/617 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53237101; called by muse, mutect2, varscan2
- RABGAP1L | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 30/595 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99275216; called by muse, mutect2
- RALGAPA2 | c.4931G>A p.R1644H | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763921980, COSV99173532; called by muse, mutect2, varscan2
- RBM10 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 388/837 reads (46%) | catalogued as COSV61307911, COSV61308269, COSV61311988; called by muse, varscan2
- RBM12 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 199/425 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs770310447; called by muse, mutect2, varscan2
- RDX | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 194/401 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1019544317, COSV58193405; called by muse, mutect2, varscan2
- RFX2 | c.1991C>T p.T664M | Missense Mutation (SNP) | VAF 185/389 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs781066965; called by muse, mutect2, varscan2
- RGS3 | c.1168C>T p.R390W (on ENST00000350696 / NM_001282923.2; = p.R278W on NM_017790.4) | Missense Mutation (SNP) | VAF 97/538 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759498418; called by muse, mutect2, varscan2
- ROS1 | c.3127G>A p.A1043T | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs747095069, COSV63857528; called by muse, mutect2, varscan2
- RPIA | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 130/281 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs748446592; called by muse, mutect2, varscan2
- RPSA | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs17856150; called by muse, mutect2, varscan2
- RTTN | c.4772G>A p.R1591Q | Missense Mutation (SNP) | VAF 209/438 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs543724689, COSV55344567; called by muse, mutect2, varscan2
- RUNX2 | c.1385del p.G462Efs*22 (on ENST00000371438; = p.G440Efs*22 on NM_001015051.3) | Frame Shift Del (DEL) | VAF 244/613 reads (40%) | catalogued as rs1561822364, COSV61840797; called by mutect2, pindel, varscan2
- S100A7L2 | c.162C>A p.Y54* | Nonsense Mutation (SNP) | VAF 116/261 reads (44%) | catalogued as COSV100906912; called by muse, mutect2, varscan2
- SBK2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 222/469 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1264260555; called by muse, mutect2, varscan2
- SEMA4F | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 252/539 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs373277680; called by muse, varscan2
- SERPINE3 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 165/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101246496; called by mutect2, varscan2
- SH3PXD2B | c.2572G>A p.V858M | Missense Mutation (SNP) | VAF 297/614 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs758060713; called by muse, mutect2, varscan2
- SIN3A | c.3788G>A p.R1263H | Missense Mutation (SNP) | VAF 218/461 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs908805435; called by muse, mutect2, varscan2
- SLC35B1 | c.521C>T p.P174L (on ENST00000649906; = p.P137L on NM_005827.4) | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs556185582, COSV99539602; called by muse, mutect2, varscan2
- SLC4A2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 195/421 reads (46%) | catalogued as COSV59655896; called by muse, mutect2, varscan2
- SMCO3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 163/391 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781434492, COSV53763605, COSV53763611; called by muse, mutect2, varscan2
- SNCAIP | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 41/488 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs141920309; called by muse, mutect2
- SOD1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs747094021; ClinVar: uncertain significance; called by muse, mutect2
- SOX15 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 388/767 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs557247017; called by muse, mutect2, varscan2
- SPEM2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 304/572 reads (53%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.872); catalogued as rs1342856745, COSV60367817; called by muse, varscan2
- SPIC | c.314del p.G105Efs*29 | Frame Shift Del (DEL) | VAF 180/444 reads (41%) | catalogued as rs1565832463, COSV54691823; called by mutect2, pindel, varscan2
- SPIRE1 | c.2219C>T p.S740L (on ENST00000409402 / NM_001128626.2; = p.S726L on NM_020148.3) | Missense Mutation (SNP) | VAF 216/438 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV104400592; called by muse, varscan2
- SRGAP2 | c.1933C>T p.P645S (on ENST00000624873 / NM_001170637.4; = p.P646S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99833435; called by muse, mutect2
- STX16 | c.712C>T p.R238* (on ENST00000371141 / NM_001001433.3; = p.R217* on NM_003763.6) | Nonsense Mutation (SNP) | VAF 228/462 reads (49%) | catalogued as rs759584494, COSV56604294; called by muse, varscan2
- SYNJ2 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 51/504 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs369496843; called by muse, mutect2
- TAF1 | c.4633C>T p.R1545W (on ENST00000373790 / NM_138923.4; = p.R1566W on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 206/425 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52120874; called by muse, varscan2
- TBCD | c.3307G>A p.G1103S | Missense Mutation (SNP) | VAF 284/553 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs772606107; called by muse, mutect2, varscan2
- TBX2 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 95/923 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV53601615; called by muse, mutect2, varscan2
- TESK2 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 181/395 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.642); catalogued as rs754978881, COSV59149445; called by muse, mutect2, varscan2
- TMEM63A | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 203/398 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as rs780727416; called by muse, varscan2
- TP73 | c.1172A>G p.Q391R | Missense Mutation (SNP) | VAF 168/352 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as rs530995550, COSV60698163; called by muse, mutect2, varscan2
- TRHDE | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 372/769 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53862529; called by muse, mutect2, varscan2
- TRO | c.2986A>G p.S996G | Missense Mutation (SNP) | VAF 226/498 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs771130837; called by muse, mutect2, varscan2
- TTBK1 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 324/661 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52489714; called by muse, mutect2, varscan2
- TUSC3 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs756614149, COSV65881118; called by muse, varscan2
- UCN | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 50/736 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1227861621; called by muse, mutect2
- UHRF1BP1 | c.4089C>T p.G1363= | Splice Region (SNP) | VAF 121/280 reads (43%) | catalogued as rs746318111; called by muse, mutect2, varscan2
- ULK1 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 335/728 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); catalogued as rs377611474; called by muse, mutect2, varscan2
- UNC13B | c.2378A>G p.Y793C | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65931801; called by muse, mutect2
- UNC45B | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 164/360 reads (46%) | catalogued as rs1237412903, COSV52096028; called by muse, mutect2, varscan2
- UNC93A | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs759479832; called by muse, mutect2, varscan2
- VDAC3 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 191/413 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.268); catalogued as rs775234791, COSV50081244; called by muse, varscan2
- VLDLR | c.2470C>T p.H824Y | Missense Mutation (SNP) | VAF 198/415 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.175); catalogued as rs1438760928; called by muse, mutect2, varscan2
- VPS26C | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 164/346 reads (47%) | catalogued as rs755537108, COSV55707328; called by muse, varscan2
- VWCE | c.1700G>A p.G567D | Missense Mutation (SNP) | VAF 116/243 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1336975943; called by muse, mutect2, varscan2
- WDR93 | c.215G>T p.W72L | Missense Mutation (SNP) | VAF 269/504 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.586); catalogued as rs200074926, COSV51532875; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 206/226 reads (91%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- ZBTB5 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 184/407 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759066956, COSV57040195; called by muse, mutect2, varscan2
- ZC3H12A | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 234/509 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1035304408; called by muse, mutect2, varscan2
- ZC3H18 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 234/485 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1337817117; called by muse, mutect2, varscan2
- ZNF536 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 245/511 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1028160142, COSV100835996; called by muse, mutect2, varscan2
- ZNF568 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 171/358 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs371204967; called by muse, mutect2, varscan2
- ZNF577 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 173/396 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752209036, COSV56814648; called by muse, mutect2, varscan2
- ZNF709 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 184/376 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV67195780; called by muse, varscan2
- ZNF83 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 268/591 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1291115034; called by muse, mutect2, varscan2
- ZNF865 | c.848del p.G283Afs*111 | Frame Shift Del (DEL) | VAF 94/311 reads (30%) | catalogued as rs1327807969; called by mutect2, varscan2
- A2ML1 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2
- ABHD6 | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 160/384 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABI3BP | c.785dup p.E263Rfs*19 | Frame Shift Ins (INS) | VAF 181/419 reads (43%) | called by mutect2, pindel, varscan2
- AC099489.1 | c.9793T>C p.C3265R | Missense Mutation (SNP) | VAF 160/294 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- AC099489.1 | c.5927G>A p.G1976E | Missense Mutation (SNP) | VAF 14/489 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.071); called by muse, mutect2
- AC242842.3 | c.2180del p.K727Rfs*23 | Frame Shift Del (DEL) | VAF 58/356 reads (16%) | called by mutect2, varscan2
- ACADVL | c.800T>C p.V267A | Missense Mutation (SNP) | VAF 164/372 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ACSL5 | c.221C>T p.A74V (on ENST00000354273; = p.A130V on NM_016234.3) | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTL6A | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 28/574 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- ADAP1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 231/493 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ADGRG4 | c.8432C>T p.T2811I | Missense Mutation (SNP) | VAF 65/744 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- AGAP2 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 84/783 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- AGXT2 | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.015); called by muse, mutect2
- AHNAK2 | c.9093dup p.S3032Lfs*132 | Frame Shift Ins (INS) | VAF 310/1521 reads (20%) | called by mutect2, pindel, varscan2
- AIFM3 | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 62/618 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- AK9 | c.5543C>A p.P1848H | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.292); called by muse, mutect2
- AKT2 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 206/411 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH3A2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ALMS1 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.267); called by muse, mutect2
- ALMS1 | c.9821C>T p.T3274I | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, varscan2
- ANKRD30BL | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 14/454 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ANKRD44 | c.1349A>G p.H450R | Missense Mutation (SNP) | VAF 211/458 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANP32A | c.225_226del p.R75Sfs*26 | Frame Shift Del (DEL) | VAF 90/298 reads (30%) | called by pindel, varscan2
- ARCN1 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 166/340 reads (49%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGAP1 | c.883dup p.S295Ffs*42 | Frame Shift Ins (INS) | VAF 208/472 reads (44%) | called by mutect2, varscan2
- ARHGEF5 | c.2699del p.P900Rfs*29 | Frame Shift Del (DEL) | VAF 80/278 reads (29%) | called by mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 267/658 reads (41%) | called by mutect2, pindel, varscan2
- ARID4A | c.2605del p.I869* | Frame Shift Del (DEL) | VAF 142/359 reads (40%) | called by mutect2, pindel, varscan2
- ARID5B | c.1291del p.E431Kfs*48 | Frame Shift Del (DEL) | VAF 203/402 reads (50%) | called by mutect2, varscan2
- ASPG | c.972C>A p.D324E | Missense Mutation (SNP) | VAF 62/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.4622C>A p.A1541D | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.368); called by muse, mutect2
- ATP13A2 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 30/696 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- ATP1A1 | c.388C>T p.L130= | Splice Region (SNP) | VAF 15/331 reads (5%) | called by muse, mutect2
- ATPSCKMT | c.187C>A p.L63I | Missense Mutation (SNP) | VAF 264/524 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- AVL9 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 108/290 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- B4GALNT3 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 28/626 reads (4%) | called by muse, mutect2
- BANP | c.173T>C p.L58S (on ENST00000286122; = p.L66S on NM_017869.4) | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); called by muse, varscan2
- BOD1L1 | c.7640C>T p.A2547V | Missense Mutation (SNP) | VAF 214/448 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTK | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 288/589 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- C2CD4C | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 87/655 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C2CD4D | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 286/581 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- C2orf42 | c.1161G>T p.L387F | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CABP2 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 61/635 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- CAMSAP1 | c.4351G>A p.A1451T | Missense Mutation (SNP) | VAF 244/529 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CARD10 | c.2504G>A p.S835N | Missense Mutation (SNP) | VAF 44/614 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- CAST | c.599C>T p.T200I (on ENST00000341926; = p.T283I on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- CCDC141 | c.1942C>A p.L648I | Missense Mutation (SNP) | VAF 189/393 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); called by mutect2, varscan2
- CCDC168 | c.12133del p.M4045Wfs*7 | Frame Shift Del (DEL) | VAF 161/430 reads (37%) | called by mutect2, pindel, varscan2
- CCDC88C | c.5290C>T p.P1764S | Missense Mutation (SNP) | VAF 162/647 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC42EP3 | c.629dup p.C211Mfs*9 | Frame Shift Ins (INS) | VAF 244/594 reads (41%) | called by mutect2, pindel, varscan2
- CELSR1 | c.2533T>C p.Y845H | Missense Mutation (SNP) | VAF 40/583 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.793); called by muse, mutect2
- CENPVL3 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 238/676 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CEP162 | c.405del p.F135Lfs*8 | Frame Shift Del (DEL) | VAF 210/478 reads (44%) | called by mutect2, pindel, varscan2
- CHD1 | c.1353del p.F451Lfs*7 | Frame Shift Del (DEL) | VAF 26/292 reads (9%) | called by mutect2, pindel
- CHD6 | c.3313C>T p.L1105F | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CHD8 | c.7427T>C p.V2476A (on ENST00000646647 / NM_001170629.2; = p.V2197A on NM_020920.4) | Missense Mutation (SNP) | VAF 252/500 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CIC | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 61/820 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); called by muse, mutect2
- CNR1 | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 148/369 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP5 | c.2705A>G p.E902G | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2
- COL12A1 | c.3626G>A p.S1209N | Missense Mutation (SNP) | VAF 167/326 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); called by muse, varscan2
- COL14A1 | c.1285A>G p.T429A | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- COL14A1 | c.2672G>C p.S891T | Missense Mutation (SNP) | VAF 35/728 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- COL2A1 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 198/457 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL6A6 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 62/449 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- CSF1R | c.1167G>T p.W389C | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); called by muse, mutect2
- CSNK2A2 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 163/344 reads (47%) | called by muse, mutect2, varscan2
- CTNS | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL9 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 319/621 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CUX2 | c.3527C>T p.A1176V | Missense Mutation (SNP) | VAF 44/833 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- CYTH1 | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2
- DBH | c.487-1G>T p.X163_splice | Splice Site (SNP) | VAF 12/366 reads (3%) | called by muse, mutect2
- DCAF15 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 26/767 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DEF8 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 32/577 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- DHX37 | c.2983G>T p.G995C | Missense Mutation (SNP) | VAF 132/262 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMD | c.5579C>T p.A1860V | Missense Mutation (SNP) | VAF 132/268 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- DNAH17 | c.11903C>T p.A3968V | Missense Mutation (SNP) | VAF 432/432 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DNAH3 | c.3844C>A p.P1282T | Missense Mutation (SNP) | VAF 176/364 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DQX1 | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 189/397 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DSCAM | c.2291A>G p.Y764C | Missense Mutation (SNP) | VAF 200/440 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.2240A>T p.E747V (on ENST00000361203 / NM_001374722.1; = p.E421V on NM_001723.6) | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- EEF1G | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 27/413 reads (7%) | called by muse, mutect2
- ELAC1 | c.722del p.K241Sfs*23 | Frame Shift Del (DEL) | VAF 174/459 reads (38%) | called by pindel, varscan2
- ELAC2 | c.1606C>A p.L536M | Missense Mutation (SNP) | VAF 244/603 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ERC1 | c.756C>G p.S252R | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ERN2 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 42/628 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- EXO1 | c.2290A>C p.S764R | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- F5 | c.4802C>G p.T1601R | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171A2 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 312/564 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, varscan2
- FAM234A | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 191/424 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- FASLG | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.2767A>G p.K923E | Missense Mutation (SNP) | VAF 202/490 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FBN3 | c.7490G>A p.G2497D | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGB | c.472A>G p.R158G | Missense Mutation (SNP) | VAF 14/333 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.403); called by muse, mutect2
- FGF23 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 290/586 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, varscan2
- FIZ1 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 318/567 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- FMR1 | c.743C>A p.P248H | Missense Mutation (SNP) | VAF 175/447 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- FNDC1 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 190/388 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FRRS1 | c.1680G>C p.Q560H | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.371); called by muse, mutect2
- GALNT10 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GDF7 | c.776del p.G259Afs*10 | Frame Shift Del (DEL) | VAF 334/833 reads (40%) | called by mutect2, pindel, varscan2
- GGT7 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 34/559 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GMNC | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- GOLM1 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 263/540 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID2IP | c.2744C>A p.A915E | Missense Mutation (SNP) | VAF 293/572 reads (51%) | SIFT tolerated (0.9); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GSTA2 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECW1 | c.628_629dup p.D211Qfs*8 | Frame Shift Ins (INS) | VAF 96/198 reads (48%) | called by mutect2, varscan2
- HELZ | c.4913G>A p.S1638N | Missense Mutation (SNP) | VAF 20/680 reads (3%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- HNRNPH2 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 106/689 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- HTR3E | c.497T>C p.I166T (on ENST00000415389 / NM_001256613.1; = p.I181T on NM_182589.2) | Missense Mutation (SNP) | VAF 212/481 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- IFT172 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 107/245 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGDCC4 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 58/846 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2
- IL27RA | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 233/531 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- IP6K2 | c.84del p.H29Tfs*56 | Frame Shift Del (DEL) | VAF 198/478 reads (41%) | called by mutect2, varscan2
- IRF2BP1 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 34/652 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.009); called by muse, mutect2
- KAT14 | c.1453A>T p.T485S | Missense Mutation (SNP) | VAF 234/457 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KCND3 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 297/621 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KCNJ14 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 56/541 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KIAA0753 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 51/412 reads (12%) | called by muse, mutect2, varscan2
- KIAA2012 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 59/348 reads (17%) | called by muse, varscan2
- KIF13A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 197/421 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- KIF21A | c.4132C>T p.Q1378* (on ENST00000361418 / NM_001378440.1; = p.Q1365* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/351 reads (15%) | called by muse, mutect2, varscan2
- KIFC3 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 293/619 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- L3MBTL2 | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 198/413 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- LAMA5 | c.3109G>A p.A1037T | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- LAMC3 | c.4280G>A p.S1427N | Missense Mutation (SNP) | VAF 64/603 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LENG9 | c.1118del p.P373Lfs*3 | Frame Shift Del (DEL) | VAF 250/636 reads (39%) | called by mutect2, pindel, varscan2
- LIPH | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 161/363 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIPI | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LMNB1 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 19/434 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2
- LMO3 | c.142G>T p.G48* | Nonsense Mutation (SNP) | VAF 234/490 reads (48%) | called by mutect2, varscan2
- LOXHD1 | c.1270del p.K424Nfs*13 | Frame Shift Del (DEL) | VAF 180/406 reads (44%) | called by mutect2, pindel, varscan2
- LPCAT1 | c.1575del p.R526Gfs*33 | Frame Shift Del (DEL) | VAF 302/766 reads (39%) | called by mutect2, pindel, varscan2
- LRRC23 | c.969G>T p.K323N | Missense Mutation (SNP) | VAF 38/493 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.157); called by muse, mutect2
- LRRC8E | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 243/542 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LRRK2 | c.5918G>T p.R1973M | Missense Mutation (SNP) | VAF 78/383 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LY6K | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LYSMD3 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 98/318 reads (31%) | called by pindel, varscan2
- MAGEA12 | c.728G>T p.R243M | Missense Mutation (SNP) | VAF 246/506 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MAGEB5 | c.152T>A p.L51Q | Missense Mutation (SNP) | VAF 288/629 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAML1 | c.1984T>C p.F662L | Missense Mutation (SNP) | VAF 133/275 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP7D1 | c.1269_1280dup p.N424_E427dup | In Frame Ins (INS) | VAF 146/410 reads (36%) | called by mutect2, varscan2
- MARCHF10 | c.1603A>G p.S535G | Missense Mutation (SNP) | VAF 165/372 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MAST2 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 191/416 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- MCC | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 19/719 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.144); called by muse, mutect2
- MED13L | c.5640G>T p.W1880C | Missense Mutation (SNP) | VAF 46/575 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEFV | c.1522del p.L508Cfs*5 | Frame Shift Del (DEL) | VAF 213/584 reads (36%) | called by mutect2, pindel, varscan2
- MEIS2 | c.392G>A p.R131H (on ENST00000561208 / NM_170675.5; = p.R118H on NM_002399.3) | Missense Mutation (SNP) | VAF 150/310 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MGAM | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 156/288 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- MGAT3 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 44/746 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- MIOS | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 172/392 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MMS22L | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 22/313 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPDZ | c.4376del p.N1459Ifs*50 | Frame Shift Del (DEL) | VAF 126/307 reads (41%) | called by mutect2, pindel, varscan2
- MUC19 | c.563G>T p.R188I | Missense Mutation (SNP) | VAF 169/379 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MYB | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 258/512 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MYH10 | c.3401G>A p.R1134Q | Missense Mutation (SNP) | VAF 212/458 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- MYLK | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 67/537 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- N4BP3 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 153/317 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAXD | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 51/949 reads (5%) | called by muse, mutect2
- NCOA5 | c.1519G>T p.G507W | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); called by muse, mutect2
- NEFL | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 46/710 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2
- NFE2L3 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 32/719 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.264); called by muse, mutect2
- NOTCH2 | c.2510G>A p.C837Y | Missense Mutation (SNP) | VAF 28/453 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR1H2 | c.1379A>G p.E460G | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NR6A1 | c.721dup p.Q241Pfs*33 (on ENST00000487099 / NM_033334.4; = p.Q236Pfs*33 on NM_001489.5) | Frame Shift Ins (INS) | VAF 236/583 reads (40%) | called by mutect2, pindel, varscan2
- NUAK2 | c.913T>G p.W305G | Missense Mutation (SNP) | VAF 52/599 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- NXF1 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 197/379 reads (52%) | called by muse, mutect2, varscan2
- NYX | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 390/745 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OPN5 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 214/454 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- OR2M3 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 63/442 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PCDHGB5 | c.244G>T p.G82W | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK6 | c.86del p.G29Afs*92 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- PCSK7 | c.1321del p.R441Gfs*33 | Frame Shift Del (DEL) | VAF 135/352 reads (38%) | called by mutect2, pindel, varscan2
- PDIA5 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 147/337 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.059); called by muse, varscan2
- PDZD2 | c.3421C>T p.Q1141* | Nonsense Mutation (SNP) | VAF 235/486 reads (48%) | called by muse, varscan2
- PGA5 | c.726C>G p.N242K | Missense Mutation (SNP) | VAF 65/651 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- PIR | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 125/245 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PITHD1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PKIB | c.139dup p.L47Pfs*17 | Frame Shift Ins (INS) | VAF 231/634 reads (36%) | called by mutect2, pindel, varscan2
- PKP1 | c.1798A>T p.I600F | Missense Mutation (SNP) | VAF 286/558 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PLA2R1 | c.3425G>A p.C1142Y | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2
- PLEKHM2 | c.770G>A p.S257N | Missense Mutation (SNP) | VAF 261/541 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- PLSCR5 | c.177A>C p.E59D | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- POF1B | c.1101C>G p.D367E | Missense Mutation (SNP) | VAF 42/469 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- POU5F2 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 267/565 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- POU6F2 | c.1528A>G p.S510G | Missense Mutation (SNP) | VAF 34/496 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); called by muse, mutect2
- PPP1R21 | c.878T>C p.I293T | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- PPP4R3A | c.727del p.T243Qfs*7 | Frame Shift Del (DEL) | VAF 191/491 reads (39%) | called by mutect2, pindel, varscan2
- PRRT1 | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 354/829 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PRTG | c.1088del p.N363Mfs*19 | Frame Shift Del (DEL) | VAF 144/345 reads (42%) | called by mutect2, pindel, varscan2
- PRXL2B | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 43/667 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); called by muse, mutect2
- PTPRS | c.1544C>A p.P515H | Missense Mutation (SNP) | VAF 26/648 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 234/510 reads (46%) | called by mutect2, pindel, varscan2
- RBM15B | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 71/660 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- REPIN1 | c.1073_1109delinsAGCACCCGCAGGACCCGATCGAAG p.G358Efs*253 | Frame Shift Del (DEL) | VAF 47/546 reads (9%) | called by pindel, varscan2*
- REPS2 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- RFWD3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 129/245 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RIMKLA | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RIMS1 | c.4830dup p.D1611* | Frame Shift Ins (INS) | VAF 148/448 reads (33%) | called by pindel, varscan2
- RIOX1 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 229/487 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- RUNDC3A | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR1 | c.15021G>T p.Q5007H | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SARDH | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- SATB2 | c.315dup p.Y106Vfs*103 | Frame Shift Ins (INS) | VAF 224/509 reads (44%) | called by mutect2, pindel, varscan2
- SERPINA2 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 263/542 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SHISA2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 63/738 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- SLC25A34 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 296/606 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC26A1 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 63/625 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by mutect2, varscan2
- SLC39A3 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 202/427 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SLC45A4 | c.316G>A p.G106R (on ENST00000517878 / NM_001286646.2; = p.G55R on NM_001080431.2) | Missense Mutation (SNP) | VAF 256/524 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- SLC49A3 | c.877A>G p.T293A (on ENST00000404286 / NM_001294341.2; = p.T292A on NM_032219.4) | Missense Mutation (SNP) | VAF 227/471 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC4A10 | c.48G>A p.T16= | Splice Region (SNP) | VAF 26/382 reads (7%) | called by muse, mutect2
- SLC6A7 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 38/663 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2
- SLC7A10 | c.1281del p.V428Wfs*56 | Frame Shift Del (DEL) | VAF 40/390 reads (10%) | called by mutect2, pindel
- SLCO3A1 | c.284T>C p.F95S | Missense Mutation (SNP) | VAF 47/702 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLX4 | c.5333T>C p.L1778P | Missense Mutation (SNP) | VAF 320/645 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRPD2 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 205/413 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, varscan2
- SNTB1 | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 74/830 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOWAHA | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 293/640 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SPEG | c.7795del p.E2599Rfs*20 | Frame Shift Del (DEL) | VAF 247/564 reads (44%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.6433G>A p.A2145T | Missense Mutation (SNP) | VAF 18/672 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.3); called by muse, mutect2
- SRCAP | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 345/646 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ST7L | c.544T>C p.Y182H | Missense Mutation (SNP) | VAF 200/408 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STAT1 | c.1601_1603dup p.D534dup | In Frame Ins (INS) | VAF 185/410 reads (45%) | called by mutect2, pindel, varscan2
- TAAR1 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, varscan2
- TACC3 | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 272/642 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF6L | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 174/395 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TARS2 | c.1236C>T p.H412= | Splice Region (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- TGM4 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 58/557 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TLN1 | c.1830G>T p.Q610H | Missense Mutation (SNP) | VAF 35/658 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- TMEM88B | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 194/492 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by mutect2, varscan2
- TNFRSF1A | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, mutect2
- TNFSF8 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 38/473 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNNT2 | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 189/377 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TNRC18 | c.1619C>A p.A540D | Missense Mutation (SNP) | VAF 331/691 reads (48%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); called by muse, varscan2
- TNS3 | c.2054G>C p.G685A | Missense Mutation (SNP) | VAF 291/592 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TRAV12-3 | c.47T>C p.L16S | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- TRIM28 | c.2402G>A p.G801D | Missense Mutation (SNP) | VAF 26/642 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM9 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 320/659 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRPM7 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TRPV5 | c.8dup p.L5Sfs*3 | Frame Shift Ins (INS) | VAF 47/495 reads (9%) | called by mutect2, pindel
- TTC38 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 17/604 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TXNDC11 | c.1675G>A p.V559I (on ENST00000356957 / NM_001303447.2; = p.V532I on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/618 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- TXNIP | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UBA2 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- UBAC1 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 272/581 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UBE4B | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2
- USP24 | c.3344A>G p.Q1115R | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); called by muse, mutect2
- USP9X | c.5806C>T p.R1936C | Missense Mutation (SNP) | VAF 198/424 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- VAC14 | c.1670G>A p.C557Y | Missense Mutation (SNP) | VAF 109/250 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VAX1 | c.725del p.P242Rfs*52 | Frame Shift Del (DEL) | VAF 156/338 reads (46%) | called by mutect2, pindel, varscan2
- WDR81 | c.1411T>C p.W471R | Missense Mutation (SNP) | VAF 35/1058 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- WRAP53 | c.647C>A p.P216H | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- YIPF2 | c.597C>A p.F199L | Missense Mutation (SNP) | VAF 62/538 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, varscan2
- ZBP1 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 235/523 reads (45%) | called by muse, mutect2, varscan2
- ZBTB14 | c.188del p.K63Sfs*14 | Frame Shift Del (DEL) | VAF 238/543 reads (44%) | called by mutect2, pindel, varscan2
- ZBTB7A | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 280/584 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZIC2 | c.1442dup p.S482Qfs*48 | Frame Shift Ins (INS) | VAF 80/292 reads (27%) | called by pindel, varscan2
- ZNF276 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 28/1002 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.322); called by muse, mutect2
- ZNF385B | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 195/380 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ZNF469 | c.634del p.Q212Rfs*134 | Frame Shift Del (DEL) | VAF 240/468 reads (51%) | called by mutect2, varscan2
- ZNF554 | c.51G>A p.Q17= | Splice Region (SNP) | VAF 22/692 reads (3%) | called by muse, mutect2
- ZNF703 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 322/657 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF775 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 40/828 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF784 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 190/402 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AAMDC | c.204C>T p.G68= | Silent (SNP) | VAF 155/334 reads (46%) | catalogued as COSV59018116; called by muse, mutect2, varscan2
- ADAM30 | c.975A>G p.L325= | Silent (SNP) | VAF 23/558 reads (4%) | called by muse, mutect2
- ADAMTS17 | c.2781G>A p.A927= | Silent (SNP) | VAF 196/384 reads (51%) | catalogued as rs750733743, COSV51491223; called by muse, varscan2
- AGBL1 | c.1884G>A p.Q628= | Silent (SNP) | VAF 48/594 reads (8%) | catalogued as COSV66853975; called by muse, mutect2
- ANO4 | c.672A>G p.T224= (on ENST00000392977 / NM_001286615.2; = p.T189= on NM_178826.4) | Silent (SNP) | VAF 181/396 reads (46%) | called by muse, mutect2, varscan2
- ARNT | c.786G>A p.S262= | Silent (SNP) | VAF 116/279 reads (42%) | catalogued as rs746660811; called by muse, mutect2, varscan2
- ARPP21 | c.1302A>G p.L434= | Silent (SNP) | VAF 28/654 reads (4%) | catalogued as COSV51804990; called by muse, mutect2
- ASCC2 | c.2175G>A p.Q725= | Silent (SNP) | VAF 22/606 reads (4%) | called by muse, mutect2
- ATP13A1 | c.2367C>T p.G789= | Silent (SNP) | VAF 354/690 reads (51%) | called by muse, mutect2, varscan2
- BBS4 | c.1080C>A p.A360= | Silent (SNP) | VAF 29/297 reads (10%) | catalogued as COSV99166512; called by muse, mutect2, varscan2
- C1orf35 | c.432G>A p.G144= | Silent (SNP) | VAF 278/578 reads (48%) | catalogued as COSV99683330; called by muse, varscan2
- C2orf16 | c.3114C>T p.Y1038= | Silent (SNP) | VAF 133/286 reads (47%) | catalogued as rs751564133, COSV62673749; called by muse, mutect2, varscan2
- CACNA1A | c.7224G>C p.P2408= | Silent (SNP) | VAF 82/944 reads (9%) | called by muse, mutect2
- CACNA1B | c.4569C>T p.I1523= | Silent (SNP) | VAF 156/325 reads (48%) | catalogued as rs767242934, COSV53127018; called by muse, mutect2, varscan2
- CCDC73 | c.780G>A p.L260= | Silent (SNP) | VAF 15/176 reads (9%) | called by muse, mutect2
- CCN5 | c.33C>A p.A11= | Silent (SNP) | VAF 210/424 reads (50%) | called by mutect2, varscan2
- CCNA2 | c.492A>G p.L164= | Silent (SNP) | VAF 144/305 reads (47%) | called by muse, mutect2, varscan2
- CD34 | c.150A>G p.S50= | Silent (SNP) | VAF 39/448 reads (9%) | called by muse, mutect2
- CFH | c.1734A>G p.L578= | Silent (SNP) | VAF 120/249 reads (48%) | called by muse, mutect2, varscan2
- CLDN15 | c.105C>T p.H35= | Silent (SNP) | VAF 26/654 reads (4%) | catalogued as rs931369449; called by muse, mutect2
- CLRN2 | c.576C>T p.C192= | Silent (SNP) | VAF 50/548 reads (9%) | catalogued as rs1292235439, COSV71825249; called by muse, mutect2
- CLSPN | c.2403T>C p.P801= | Silent (SNP) | VAF 264/531 reads (50%) | called by muse, mutect2, varscan2
- CSE1L | c.783C>T p.A261= | Silent (SNP) | VAF 102/216 reads (47%) | catalogued as rs1162656804; called by muse, varscan2
- CYP2D7 | c.282C>T p.R94= | Silent (SNP) | VAF 103/627 reads (16%) | catalogued as rs749552077, COSV63852786; called by muse, mutect2, varscan2
- DACT3 | c.81C>T p.L27= | Silent (SNP) | VAF 334/647 reads (52%) | called by muse, mutect2, varscan2
- DEPDC5 | c.1362C>T p.P454= | Silent (SNP) | VAF 56/668 reads (8%) | catalogued as rs772622894; called by muse, mutect2
- DET1 | c.735T>C p.T245= (on ENST00000268148 / NM_001144074.3; = p.T256= on NM_017996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 208/403 reads (52%) | called by muse, mutect2, varscan2
- DGCR8 | c.198C>A p.P66= | Silent (SNP) | VAF 247/529 reads (47%) | catalogued as rs770483438; called by muse, mutect2, varscan2
- DHX29 | c.1488G>A p.L496= | Silent (SNP) | VAF 27/469 reads (6%) | called by muse, mutect2
- DKK4 | c.183G>A p.P61= | Silent (SNP) | VAF 217/447 reads (49%) | catalogued as rs200089567; called by muse, mutect2, varscan2
- DNAH3 | c.1338G>A p.S446= | Silent (SNP) | VAF 242/520 reads (47%) | catalogued as rs760266087; called by muse, mutect2
- DNAJC10 | c.1473A>G p.R491= | Silent (SNP) | VAF 171/356 reads (48%) | called by muse, mutect2, varscan2
- DOP1B | c.531C>T p.G177= | Silent (SNP) | VAF 46/600 reads (8%) | called by muse, mutect2
- EHBP1L1 | c.2742C>A p.S914= | Silent (SNP) | VAF 177/349 reads (51%) | catalogued as COSV100500013; called by muse, mutect2, varscan2
- EMG1 | c.510A>C p.G170= | Silent (SNP) | VAF 149/353 reads (42%) | called by muse, mutect2, varscan2
- ERCC2 | c.1167C>T p.T389= | Silent (SNP) | VAF 201/422 reads (48%) | catalogued as rs765430756, COSV55539158; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM162A | c.333G>A p.T111= | Silent (SNP) | VAF 245/486 reads (50%) | catalogued as rs771323822; called by muse, mutect2, varscan2
- FARSA | c.642C>A p.A214= | Silent (SNP) | VAF 192/422 reads (45%) | called by muse, mutect2, varscan2
- FAXDC2 | c.517C>T p.L173= | Silent (SNP) | VAF 27/529 reads (5%) | called by muse, mutect2
- FBXO2 | c.279G>A p.Q93= | Silent (SNP) | VAF 274/587 reads (47%) | called by muse, mutect2, varscan2
- FOXO4 | c.288C>A p.S96= | Silent (SNP) | VAF 462/882 reads (52%) | called by muse, mutect2, varscan2
- GCM2 | c.9G>A p.A3= | Silent (SNP) | VAF 207/458 reads (45%) | catalogued as COSV65275735; called by muse, mutect2, varscan2
- GNPAT | c.1242C>T p.G414= | Silent (SNP) | VAF 30/428 reads (7%) | called by muse, mutect2
- GPR1 | c.327G>A p.L109= | Silent (SNP) | VAF 42/610 reads (7%) | called by muse, mutect2
- HCLS1 | c.1110T>C p.P370= | Silent (SNP) | VAF 228/524 reads (44%) | catalogued as COSV100101358; called by muse, varscan2
- HDAC5 | c.3138G>A p.T1046= | Silent (SNP) | VAF 177/363 reads (49%) | catalogued as rs575454875; called by muse, mutect2, varscan2
- HOXA6 | c.351C>T p.S117= | Silent (SNP) | VAF 240/500 reads (48%) | catalogued as rs777734969; called by muse, varscan2
- HSPG2 | c.7893G>T p.P2631= | Silent (SNP) | VAF 201/446 reads (45%) | catalogued as rs571876580, COSV65975390; called by muse, mutect2, varscan2
- HTR2A | c.861T>C p.S287= | Silent (SNP) | VAF 230/448 reads (51%) | called by muse, mutect2, varscan2
- IDH3G | c.432C>T p.N144= | Silent (SNP) | VAF 154/363 reads (42%) | catalogued as rs1557069595; called by muse, mutect2, varscan2
- IFT46 | c.543G>A p.T181= (on ENST00000264021 / NM_001168618.2; = p.T232= on NM_020153.3) | Silent (SNP) | VAF 173/366 reads (47%) | catalogued as rs782395090, COSV50595718; called by muse, mutect2, varscan2
- IMMT | c.2028G>A p.P676= | Silent (SNP) | VAF 164/377 reads (44%) | catalogued as rs771706844; called by muse, mutect2, varscan2
- IRS1 | c.804C>T p.S268= | Silent (SNP) | VAF 220/480 reads (46%) | called by muse, mutect2, varscan2
- IRX1 | c.54C>T p.G18= | Silent (SNP) | VAF 104/189 reads (55%) | catalogued as rs1298565849; called by muse, mutect2, varscan2
- IRX4 | c.252C>T p.G84= | Silent (SNP) | VAF 23/782 reads (3%) | catalogued as rs947763808; called by muse, mutect2
- ITGB5 | c.396G>A p.Q132= | Silent (SNP) | VAF 19/318 reads (6%) | called by muse, mutect2
- ITGB6 | c.840C>T p.S280= | Silent (SNP) | VAF 225/500 reads (45%) | catalogued as rs1294643213; called by muse, mutect2, varscan2
- KCNK15 | c.927C>T p.P309= | Silent (SNP) | VAF 19/552 reads (3%) | called by muse, mutect2
- KIF19 | c.2754C>T p.R918= | Silent (SNP) | VAF 256/546 reads (47%) | catalogued as rs1267352379; called by muse, mutect2, varscan2
- KPNA5 | c.906G>A p.L302= | Silent (SNP) | VAF 121/241 reads (50%) | called by muse, mutect2, varscan2
- KRT15 | c.1008G>A p.L336= | Silent (SNP) | VAF 193/370 reads (52%) | catalogued as COSV54179308; called by muse, mutect2, varscan2
- KRTAP6-3 | c.150C>T p.G50= | Silent (SNP) | VAF 393/810 reads (49%) | catalogued as rs778383968, COSV66963375; called by muse, mutect2
- L3MBTL1 | c.1431C>T p.D477= (on ENST00000418998 / NM_001377303.1; = p.D387= on NM_015478.7) | Silent (SNP) | VAF 34/386 reads (9%) | called by muse, mutect2
- LAMB4 | c.4932C>T p.H1644= | Silent (SNP) | VAF 192/459 reads (42%) | catalogued as rs138458523; called by muse, mutect2, varscan2
- LMTK2 | c.132C>A p.S44= | Silent (SNP) | VAF 29/304 reads (10%) | called by muse, mutect2, varscan2
- LONRF1 | c.24G>A p.R8= | Silent (SNP) | VAF 39/420 reads (9%) | called by muse, mutect2
- MAD1L1 | c.564G>A p.Q188= | Silent (SNP) | VAF 34/458 reads (7%) | called by muse, mutect2
- MAP2K1 | c.900C>T p.Y300= | Silent (SNP) | VAF 125/268 reads (47%) | catalogued as rs147333830; called by muse, varscan2
- MAPK4 | c.507C>T p.F169= | Silent (SNP) | VAF 210/434 reads (48%) | catalogued as rs762000392, COSV68543795; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2364C>T p.I788= | Silent (SNP) | VAF 274/575 reads (48%) | catalogued as rs772096961; called by muse, mutect2, varscan2
- MC2R | c.423C>T p.I141= | Silent (SNP) | VAF 254/514 reads (49%) | catalogued as rs149161443, COSV59621017; called by muse, varscan2
- MLLT3 | c.1392C>T p.H464= | Silent (SNP) | VAF 115/246 reads (47%) | catalogued as rs769616095; called by muse, mutect2, varscan2
- MLYCD | c.271C>T p.L91= | Silent (SNP) | VAF 29/989 reads (3%) | called by muse, mutect2
- MPND | c.159C>A p.G53= | Silent (SNP) | VAF 263/570 reads (46%) | called by mutect2, varscan2
- MRGPRX4 | c.120C>T p.V40= | Silent (SNP) | VAF 237/486 reads (49%) | catalogued as rs759803894, COSV100049725; called by muse, mutect2, varscan2
- MRM1 | c.708C>T p.S236= | Silent (SNP) | VAF 26/722 reads (4%) | catalogued as rs186312052; called by muse, mutect2
- NCAPG2 | c.2080C>T p.L694= | Silent (SNP) | VAF 180/382 reads (47%) | called by muse, mutect2, varscan2
- NFKBIE | c.633C>A p.T211= (on ENST00000275015; = p.T72= on NM_004556.3) | Silent (SNP) | VAF 65/780 reads (8%) | called by muse, mutect2
- NFKBIL1 | c.517C>T p.L173= | Silent (SNP) | VAF 43/781 reads (6%) | called by muse, mutect2
- NKX6-2 | c.192G>A p.L64= | Silent (SNP) | VAF 43/621 reads (7%) | called by muse, mutect2
- NRGN | c.60G>A p.P20= | Silent (SNP) | VAF 313/628 reads (50%) | catalogued as COSV99423402; called by muse, mutect2, varscan2
- NTSR1 | c.328C>T p.L110= | Silent (SNP) | VAF 74/763 reads (10%) | called by muse, mutect2
- OBSCN | c.21786C>T p.T7262= | Silent (SNP) | VAF 28/854 reads (3%) | catalogued as rs1332554034; called by muse, mutect2
- OCIAD1 | c.66G>A p.G22= | Silent (SNP) | VAF 138/341 reads (40%) | catalogued as rs144906055; called by muse, mutect2, varscan2
- OR10W1 | c.21C>T p.A7= | Silent (SNP) | VAF 36/404 reads (9%) | called by muse, mutect2
- OR8K1 | c.840C>A p.A280= | Silent (SNP) | VAF 80/499 reads (16%) | called by muse, mutect2, varscan2
- PABPC4 | c.123G>A p.R41= | Silent (SNP) | VAF 45/842 reads (5%) | catalogued as rs117264627; called by muse, mutect2
- PARD3B | c.2166A>G p.S722= | Silent (SNP) | VAF 243/520 reads (47%) | called by muse, mutect2, varscan2
- PCDHA6 | c.390G>A p.P130= | Silent (SNP) | VAF 105/575 reads (18%) | catalogued as rs370641869; called by muse, mutect2, varscan2
- PCDHGA4 | c.1665G>A p.Q555= | Silent (SNP) | VAF 208/428 reads (49%) | called by muse, mutect2, varscan2
- PEPD | c.1293C>T p.R431= | Silent (SNP) | VAF 414/909 reads (46%) | catalogued as rs758148546, COSV99728746; called by muse, mutect2
- PHF12 | c.2634G>A p.P878= | Silent (SNP) | VAF 189/433 reads (44%) | catalogued as rs765713112, COSV60453457; called by muse, mutect2, varscan2
- PHYHD1 | c.450C>T p.G150= | Silent (SNP) | VAF 229/478 reads (48%) | catalogued as rs781740579; called by muse, mutect2, varscan2
- PI4KA | c.5367C>T p.Y1789= | Silent (SNP) | VAF 58/574 reads (10%) | called by muse, mutect2
- PLCG2 | c.1341G>A p.L447= | Silent (SNP) | VAF 36/409 reads (9%) | called by muse, mutect2
- PLEC | c.13512G>A p.K4504= (on ENST00000322810 / NM_201380.4; = p.K4394= on NM_000445.5) | Silent (SNP) | VAF 28/736 reads (4%) | called by muse, mutect2
- PMVK | c.150G>A p.Q50= | Silent (SNP) | VAF 155/336 reads (46%) | called by muse, mutect2
- PNPLA7 | c.2442C>T p.C814= | Silent (SNP) | VAF 334/677 reads (49%) | catalogued as rs146395931; called by muse, mutect2, varscan2
- PREX2 | c.3102G>A p.Q1034= | Silent (SNP) | VAF 165/327 reads (50%) | catalogued as COSV99910413; called by muse, mutect2, varscan2
- PTPRF | c.3027G>A p.P1009= | Silent (SNP) | VAF 40/375 reads (11%) | catalogued as rs570067770, COSV63445901; called by muse, mutect2, varscan2
- PYGB | c.621G>A p.V207= | Silent (SNP) | VAF 25/468 reads (5%) | called by muse, mutect2
- RAPGEF1 | c.396G>A p.L132= | Silent (SNP) | VAF 28/562 reads (5%) | called by muse, mutect2
- RBIS | c.273T>C p.D91= | Silent (SNP) | VAF 137/319 reads (43%) | catalogued as rs998249753; called by muse, mutect2, varscan2
- RNASE3 | c.327C>T p.H109= | Silent (SNP) | VAF 231/498 reads (46%) | called by muse, mutect2, varscan2
- RTF1 | c.1113C>T p.R371= | Silent (SNP) | VAF 216/455 reads (47%) | catalogued as rs970740941; called by muse, mutect2, varscan2
- SCAP | c.591G>A p.Q197= | Silent (SNP) | VAF 22/460 reads (5%) | catalogued as rs1466299615; called by muse, mutect2
- SETD5 | c.1917G>A p.Q639= | Silent (SNP) | VAF 173/352 reads (49%) | catalogued as COSV56717630; called by muse, mutect2, varscan2
- SKIDA1 | c.1338G>C p.S446= | Silent (SNP) | VAF 48/679 reads (7%) | called by muse, mutect2
- SLC26A6 | c.807T>C p.T269= | Silent (SNP) | VAF 44/678 reads (6%) | called by muse, mutect2
- SMAP1 | c.1236G>A p.P412= (on ENST00000370455 / NM_001044305.3; = p.P385= on NM_021940.5) | Silent (SNP) | VAF 171/335 reads (51%) | catalogued as rs771439200, COSV100016783; called by muse, mutect2, varscan2
- SMARCA2 | c.756G>A p.Q252= | Silent (SNP) | VAF 70/700 reads (10%) | catalogued as COSV61808346; called by muse, mutect2, varscan2
- SMARCA2 | c.3846C>T p.S1282= | Silent (SNP) | VAF 22/518 reads (4%) | called by muse, mutect2
- SMIM32 | c.12C>T p.D4= | Silent (SNP) | VAF 43/529 reads (8%) | called by muse, mutect2
- SMOX | c.1506G>A p.P502= | Silent (SNP) | VAF 145/335 reads (43%) | catalogued as rs138385253; called by muse, mutect2, varscan2
- SOGA1 | c.2053C>T p.L685= | Silent (SNP) | VAF 301/553 reads (54%) | called by muse, mutect2, varscan2
- SSTR5 | c.561C>T p.N187= | Silent (SNP) | VAF 393/757 reads (52%) | catalogued as rs781048519, COSV53513231; called by muse, mutect2, varscan2
- SUMF1 | c.1110G>A p.L370= | Silent (SNP) | VAF 162/382 reads (42%) | called by muse, mutect2
- SUZ12 | c.1912C>T p.L638= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as COSV59498787; called by muse, mutect2
- SYT16 | c.1704G>A p.Q568= | Silent (SNP) | VAF 216/448 reads (48%) | called by muse, varscan2
- TBC1D10B | c.87G>A p.R29= | Silent (SNP) | VAF 75/893 reads (8%) | called by muse, mutect2
- TBX22 | c.723G>A p.L241= | Silent (SNP) | VAF 55/793 reads (7%) | called by muse, mutect2
- TMEM120B | c.624T>C p.N208= | Silent (SNP) | VAF 175/397 reads (44%) | catalogued as rs1336298793; called by muse, mutect2, varscan2
- TMEM151B | c.48C>T p.G16= | Silent (SNP) | VAF 47/604 reads (8%) | called by muse, mutect2
- TMEM200B | c.879C>T p.G293= | Silent (SNP) | VAF 60/654 reads (9%) | called by muse, mutect2
- TNFRSF6B | c.753G>A p.A251= | Silent (SNP) | VAF 366/744 reads (49%) | catalogued as rs550888663; called by muse, varscan2
- TRIM66 | c.1149G>A p.L383= | Silent (SNP) | VAF 23/736 reads (3%) | called by muse, mutect2
- TRMT2A | c.583C>T p.L195= | Silent (SNP) | VAF 35/332 reads (11%) | called by muse, mutect2, varscan2
- TTC12 | c.1917G>A p.A639= | Silent (SNP) | VAF 185/426 reads (43%) | catalogued as rs147254715; called by muse, mutect2, varscan2
- TTYH1 | c.432G>T p.V144= | Silent (SNP) | VAF 29/556 reads (5%) | called by muse, mutect2
- UNC13B | c.3408C>T p.H1136= | Silent (SNP) | VAF 205/430 reads (48%) | called by muse, mutect2, varscan2
- VPS26C | c.654G>A p.T218= | Silent (SNP) | VAF 123/299 reads (41%) | catalogued as rs751555249; called by muse, varscan2
- WARS2 | c.858C>T p.S286= | Silent (SNP) | VAF 402/817 reads (49%) | called by muse, mutect2, varscan2
- WDR97 | c.1563G>A p.A521= | Silent (SNP) | VAF 352/684 reads (51%) | called by muse, varscan2
- ZC3H14 | c.2034T>C p.S678= | Silent (SNP) | VAF 220/436 reads (50%) | catalogued as rs368987763; called by muse, mutect2, varscan2
- ZC3H7B | c.354G>A p.A118= | Silent (SNP) | VAF 274/576 reads (48%) | catalogued as rs149790062; called by muse, varscan2
- ZNF205 | c.1512C>T p.Y504= | Silent (SNP) | VAF 401/797 reads (50%) | catalogued as rs1260177735, COSV54620692; called by muse, mutect2, varscan2
- ZNF358 | c.234G>A p.P78= | Silent (SNP) | VAF 278/571 reads (49%) | catalogued as rs1450293906, COSV51175224; called by muse, mutect2, varscan2
- ZSCAN10 | c.810C>T p.G270= (on ENST00000252463; = p.G325= on NM_032805.3) | Silent (SNP) | VAF 50/575 reads (9%) | catalogued as rs1425392531; called by muse, mutect2
- ZSWIM9 | c.240C>T p.C80= | Silent (SNP) | VAF 19/718 reads (3%) | called by muse, mutect2
- AGAP14P | n.1972A>G | RNA (SNP) | VAF 356/475 reads (75%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+2793dup | Intron (INS) | VAF 52/134 reads (39%) | catalogued as rs961229134; called by mutect2, varscan2
- C5orf60 | n.1708C>T | RNA (SNP) | VAF 44/518 reads (8%) | called by muse, mutect2, varscan2
- CC2D2B | c.780+5040A>G | Intron (SNP) | VAF 15/241 reads (6%) | called by muse, mutect2
- FBF1 | c.*994A>G | 3'UTR (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- KCNC4 | c.*630C>T | 3'UTR (SNP) | VAF 52/864 reads (6%) | catalogued as rs765594655; called by muse, mutect2
- KDM4C | c.2994+115dup | Intron (INS) | VAF 13/33 reads (39%) | catalogued as rs771386100; called by mutect2, varscan2
- KRTCAP3 | chr2:27446300 G>T | 3'Flank (SNP) | VAF 18/476 reads (4%) | called by muse, mutect2
- MFRP | chr11:119346363 G>A | 5'Flank (SNP) | VAF 22/491 reads (4%) | catalogued as rs1437048240; called by muse, mutect2
- MYOM3 | c.3424-186A>G | Intron (SNP) | VAF 170/383 reads (44%) | called by muse, mutect2, varscan2
- NR4A1 | c.876+16A>G | Intron (SNP) | VAF 340/686 reads (50%) | called by muse, mutect2, varscan2
- OSR2 | c.-65G>A | 5'UTR (SNP) | VAF 205/473 reads (43%) | catalogued as COSV52559440; called by muse, mutect2, varscan2
- PXN | c.832-1247T>C | Intron (SNP) | VAF 278/634 reads (44%) | catalogued as rs760465623; called by muse, mutect2, varscan2
- RHOC | c.*79A>T | 3'UTR (SNP) | VAF 38/490 reads (8%) | called by muse, mutect2
- SLC39A1 | c.*831del | 3'UTR (DEL) | VAF 155/441 reads (35%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.612-44G>A | Intron (SNP) | VAF 215/504 reads (43%) | catalogued as rs1197072744; called by muse, mutect2, varscan2
- SPRTN | chr1:231338165 ins T | 5'Flank (INS) | VAF 160/378 reads (42%) | catalogued as rs1558359486; called by mutect2, varscan2
- TAL1 | c.*2082G>T | 3'UTR (SNP) | VAF 42/610 reads (7%) | called by muse, mutect2
- TSHR | c.692+207del | Intron (DEL) | VAF 195/525 reads (37%) | called by mutect2, pindel, varscan2
- UNC13B | c.762-5614_762-5612del | Intron (DEL) | VAF 148/319 reads (46%) | called by pindel, varscan2
- VPS11 | c.-784T>C | 5'UTR (SNP) | VAF 13/325 reads (4%) | called by muse, mutect2
- ZNF585A | c.-71C>A | 5'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
